Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HY, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HY-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. RIGHT KNEE MASS, RESECTION:
Subcutaneous leiomyosarcoma (see Key Pathologic Findings).

KEY PATHOLOGIC FINDINGS:

Tumor type: Leiomyosarcoma.
Tumor size: 2.6 x 2.1 x 0.7 cm.
Tumor grade: 2-3 of 3.
Mitotic count: Up to 12 mitoses per 10 high-power fields.
Tumor necrosis: Focally present.
Angiolymphatic invasion: Not present.
Surgical margins: Free of tumor. The closest negative 6 to 12 o'clock margin is 1.0 mm.
Pathologic stage: pT1a, pNx, pMx.

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed
Out by _____

Specimen(s) Received

- A. RIGHT KNEE MASS FS

ICD-O-3
Leiomyosarcoma NOS 8890/3
Site: Knee NOS C49.2
QW 4/22/14

Clinical History

NONE.

Preoperative Diagnosis

RIGHT KNEE SOFT TISSUE SARCOMA.

Intraoperative Consultation

FSA1-FSA2 RIGHT KNEE MASS:
Leiomyosarcoma. Margin negative.

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr. _____ the _____ at _____.

I, _____, M.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

[page 2 of 2]
A. Specimen A is received fresh for frozen section consult, labeled "right knee mass: short-6 o'clock, long-3 o'clock." The specimen consists of a pale tan-white oriented skin ellipse, 4.4 x 3.2 cm, excised to a depth of 2.2 cm. The skin exhibits a firm irregular lesion with an indistinct border, 2.6 x 2.1 x 0.7 cm. The margins are inked as follows: blue-12 to 6, green-6 to 12, deep-black.

The cut surfaces exhibit a rubbery, whorled, mass, extending 1.3 cm depth, and 7 mm from deep margin. The lesion extends to the green inked margin by 1 mm. Neither necrosis nor hemorrhage is identified. The surrounding tissue is soft and congested. The tumor is submitted entirely in as labeled:

FSA1: Frozen section of skin lesion with tumor, cross section
FSA2: Frozen section of skin lesion with tumor, green margin (closest)
A3: Mirror image of lesion for ...
A4-A8: Skin lesion with tumor, cross section

The specimen is submitted for

HIFAA Discrepancy		/

Source: NCI Genomic Data Commons file 81d51ac4-e9f1-4b80-b937-21b369db243c (TCGA-3B-A9HY.EC857056-27C8-4ECD-9140-52D4AC8F4818.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).